Surgical pathology report (de-identified scan), TCGA case TCGA-ZH-A8Y8, project TCGA-CHOL (Cholangiocarcinoma), tissue source site University of North Carolina, specimen TCGA-ZH-A8Y8-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3

C holangiocarcinoma S160/3
Site: Intrahepatic bile duct
C22.1

Q40 4/3/14

Diagnosis:

A: Lymph node, hepatoduodenal, biopsy

- One benign lymph node, negative for metastatic carcinoma (0/1)

B: Liver, left lobe, partial hepatectomy

Histologic tumor type/subtype: cholangiocarcinoma (see comment)

Histologic grade: moderately differentiated

Tumor location: left lobe

Tumor size: 3.9 cm (gross measurement)

Focality: unifocal

Tumor growth pattern: mass forming

Tumor necrosis/treatment effect: scattered associated tumor necrosis present (no known prior treatment)

Vascular invasion: not identified

Perineural invasion: focally present

Capsular invasion: not identified

Margins: parenchymal margin is uninvolved by tumor, 2.1 cm away

Lymph nodes: see specimen A

Background liver: scattered mild chronic inflammation, minimal microvesicular steatosis involving less than 5% of the hepatic parenchyma, and mildly increased portal fibrosis

AJCC Pathologic TNM Stage: pT1 pN0

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

[page 2 of 3]
Comment:

Based on the lack of clinical or radiologic evidence to support the presence of a primary adenocarcinoma arising outside of the liver, the presence of a 3.9 cm solitary mass in the left liver lobe consisting of moderately differentiated adenocarcinoma is consistent with a diagnosis of cholangiocarcinoma.

Special stains are performed on a section of liver parenchyma away from the tumor mass. The liver is negative for significant iron deposition. There is no evidence of alpha-1-antitrypsin deficiency (no DPAS positive globules identified within hepatocytes). A trichrome stain shows a mild increase in portal fibrosis. A reticulin stain also highlights the mild increase in fibrosis with an otherwise normal hepatic plate thickness.

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by Dr. in OR .
Specimen delivery time is

FSA1: Lymph node, hepatoduodenal, biopsy

- No tumor seen. Moderate number of MN giant cells, histiocytosis.

Drs. on at

Frozen Section Pathologist: , MD

Clinical History:

-year-old male with a liver adenocarcinoma favoring cholangiocarcinoma, questionable primary upper GI or biliary tree.

Gross Description:

Received are two appropriately labeled containers. Specimen A is received fresh for frozen section.

Container A is additionally labeled "hepatoduodenal lymph node for frozen section." It consist of a 2.2 x 2.0 x 1.0 cm green/brown lymph node candidate. The specimen is serially sectioned and entirely submitted for frozen section and resubmitted in block FSA1 and FSA2,

Container B:

Specimen Type: left lobectomy

[page 3 of 3]
Specimen Weight: 355 grams

Measurement: 15.0 x 14.4 x 3.5 cm

Orientation: The specimen is received with a stitch marking the caudal cut margin. The surgical cut margin is inked blue.

Capsule: red/brown and smooth

Mass: 3.9 x 3.5 x 2.2 cm; The mass is within the specimen; it is near the falciform ligament. The mass is tan/white and firm with relatively circumscribed edges.

Distance from the capsule: 0.5 cm

Distance from the inked surgical margin: 2.2 cm; no necrosis is seen

Adjacent liver tissue: tan/brown, firm and unremarkable

Major portal vein/ hepatic vein: n/a

Gallbladder: n/a

Other comments: Tissue and normal tissue to Tissue Procurement.

Block Summary:

B1 - ductal structures, en face
B2 - mass with respect to capsule
B3 - mass with respect to surgical margin, bisected
B4,B5 - sections of tumor with respect to bile duct
B6 - normal liver parenchyma
Tissue remains.

Prior Malignancy History	Prostate	✓

Source: NCI Genomic Data Commons file 9b4bde39-fad7-4016-b980-3317eddfec2f (TCGA-ZH-A8Y8.D35938C2-CFED-444E-8284-B1A4D5EAD0F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).